Surgical pathology report (de-identified scan), TCGA case TCGA-46-3765, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-3765-01A (Primary Tumor).

[page 1 of 4]
TISSUES:

A. LUNG-RIGHT UPPER LOBE

B. LYMPH NODE

Edited by:

CODES:

T08000 - LYMPH NODE

T28200/M941 - RT UP LOBE LUNG/SQUAMOUS CARCIN

Edited by:

ICD CODES: 162.9 - MAL NEO BRONCH/LUNG NOS

Edited by:

MARKERS: 88305, 88305TC, 88309, 88309TC, 88313, SPECIAL STAINS - GRP II, RES, RLN,
SURGICAL SPECIMEN

Edited by:

PROCEDURES:

Continued on next page ...

[page 2 of 4]
CLINICAL HISTORY

PRE-OPERATIVE DIAGNOSIS: RIGHT LUNG CA

Edited by:

FINAL DIAGNOSIS

A. LUNG, RIGHT UPPER LOBE, LOBECTOMY:

- SQUAMOUS CELL CARCINOMA. SEE SYNOPTIC REPORT.

B. LYMPH NODE, APICAL SEGMENT, BIOPSY:

- LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

Dictated by

Edited by:

GROSS DESCRIPTION

A. The specimen is submitted fresh as "right upper lobe" and consists of a 360 gram (formalin fixed), 20 x 9.5 x 5 cm lung lobe received with multiple stapled margins measuring 5 to 9.5 cm in length with a 2 cm in length stapled bronchial margin at the hilum and multiple vascular margins measuring 0.3 cm in length and 0.3 cm in diameter to 0.5 cm in length and 0.6 cm in diameter. The pleural surface is purple to gray, dull and dusky with multiple tan brown membranous adhesions and a firm puckered and somewhat indurated area. The pleural surface surrounding the area is inked blue. The stapled margins are removed and the underlying parenchyma inked black. Sectioning reveals a 2.7 x 2.3 x 2 cm well circumscribed tan white firm mass with a centrally hemorrhagic area corresponding to the previously described puckered area on the pleural surface which grossly appears to abut the blue inked pleura, measuring 5 cm from the bronchial margin and 1.8 cm from the closest black inked parenchyma underlying the stapled resection margins. The remaining parenchyma is pink red to brown, spongy, homogenous, showing a 2 cm well circumscribed cyst-like structure measuring 8 cm from the previously described mass and 1.5 cm from the closest pleural surface showing no evidence of masses or nodularities and is otherwise grossly unremarkable. No other discrete masses or

Continued on next page ...

[page 3 of 4]
GROSS DESCRIPTION

(Continued)

nodularities are grossly identified. No hilar lymph nodes are grossly palpated. Representative sections are submitted, multiple (8) as follows:

- 1: Vascular and bronchial margins submitted en face
- 2: Mass with closest pleural surface
- 3 and 4: Additional sections of mass with adjacent parenchyma
- 5: Perpendicular section of stapled margin closest to mass
- 6: Cyst-like structure within parenchyma
- 7: Dull dusky pleural surface with membranous adhesions
- 8: Uninvolved parenchyma and pleural surface

B. The specimen is submitted fresh as "apical segment node" and consists of a 0.3 cm gray black ovoid possible lymph node which is submitted entirely intact, 1 (1).

Dictated by
Edited by:

SURGICAL PROCEDURES:

RESECTION, REGIONAL LYMPH

Edited by:

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
LATERALITY: RIGHT
TUMOR SITE: RIGHT UPPER LOBE
TUMOR SIZE: 2.7 CM
HISTOLOGIC TYPE: SQUAMOUS
HISTOLOGIC GRADE: 2-3 (MODERATE TO POORLY DIFFERENTIATED)
EXTENT OF INVASION: CONFINED TO LUNG
EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): NOT IDENTIFIED

MARGINS:

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
DISTANCE TO PERTINENT MARGIN(S): 5 CM FROM THE BRONCHIAL
MARGIN AND 1.8 CM FROM THE PARENCHYMAL MARGIN.

VENOUS INVASION: ABSENT
ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE:

Continued on next page ...

[page 4 of 4]
SYNOPTIC REPORT

(Continued)

N1 - # INVOLVED/# EXAMINED: 0/5
N2 - # INVOLVED/#EXAMINED: 0/10+
N3 - # INVOLVED/# EXAMINED: 0/0

ADDITIONAL PERTINENT FINDINGS:

- THE TUMOR CELLS SHOW NO DEFINITE CYTOPLASMIC MUCIN PRODUCTION ON A MUCICARMINE STAIN.
- FOCAL PLEURAL ADHESION AWAY FROM TUMOR.
- NON-NEOPLASTIC LUNG SHOWS NO SIGNIFICANT ABNORMALITY.

PTNM STAGE: pT1 N0 MX

Dictated by
Edited by:

Prelim:

Final:

*** End of Report ***

Source: NCI Genomic Data Commons file a4adbbef-66b9-492e-a7b3-7cc5bcb9077f (TCGA-46-3765.70F74440-E1DA-4D78-9B0D-633342C3B4C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).